Somatic mutation profile of tumor specimen MP2PRT-PAUFRZ-TMP1-A (aliquot MP2PRT-PAUFRZ-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUFRZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.7 years (996 days).
Specimen MP2PRT-PAUFRZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed5c8884-c024-4765-ae70-e34ef2cd59b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFRZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFRZ-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5460a622-bce1-4969-a4dc-e5b96a2cef4e

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRACD | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 110/406 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs373287876; called by muse, mutect2, varscan2
- FERMT1 | c.1966C>A p.R656S | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372047057; called by muse, mutect2, varscan2
- HTR5A | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as rs149355608, COSV55287916; called by muse, mutect2
- OR10H2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 162/583 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs760744077; called by muse, mutect2, varscan2
- OR2L2 | c.810C>A p.D270E | Missense Mutation (SNP) | VAF 82/211 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs777289994; called by muse, mutect2, varscan2
- TMPRSS11E | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 85/361 reads (24%) | catalogued as rs1245131954, COSV59518027; called by muse, mutect2, varscan2
- TRRAP | c.4166C>T p.A1389V | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs782112743; called by muse, mutect2, varscan2
- CREBBP | c.5012C>T p.A1671V | Missense Mutation (SNP) | VAF 174/479 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CUBN | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- LETM1 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 25/636 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- IGHV3-11 | chr14:106116633 del TGT | Silent (DEL) | VAF 35/123 reads (28%) | called by pindel*, varscan2
